Surgical pathology report (de-identified scan), TCGA case TCGA-24-1558, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site Washington University, specimen TCGA-24-1558-01A (Primary Tumor).

[page 1 of 3]
24-1558

Other Related Clinical Data:

DIAGNOSIS: OVARY, RIGHT AND LEFT, BILATERAL SALPINGO-OOPHORECTOMY (INCLUDING FS1A)
- POORLY DIFFERENTIATED SEROUS CARCINOMA (SEE COMMENT)

FALLOPIAN TUBE, RIGHT AND LEFT, BILATERAL SALPINGO-OOPHORECTOMY
- FOCAL PERITUBAL CARCINOMA

UTERUS, ENDOMETRIUM, TOTAL ABDOMINAL HYSTERECTOMY (INCLUDING FS1B)
- INACTIVE ENDOMETRIUM WITH CYSTIC ATROPHY
- ENDOMETRIAL POLYP (7.5 CM IN GREATEST DIMENSION)

UTERUS, MYOMETRIUM, TOTAL ABDOMINAL HYSTERECTOMY
- POORLY DIFFERENTIATED CARCINOMA IN SUBSEROSAL MYOMETRIUM
- LEIOMYOMA (1.4 CM)

UTERUS, SEROSA, TOTAL ABDOMINAL HYSTERECTOMY
- METASTATIC POORLY DIFFERENTIATED CARCINOMA

UTERUS, CERVIX, TOTAL ABDOMINAL HYSTERECTOMY
- CHRONIC CERVICITIS

OMENTUM, EXCISION
- METASTATIC , EXTENSIVE POORLY-DIFFERENTIATED CARCINOMA

APPENDIX, EXCISION
- LUMENAL FIBROSIS
- METASTATIC POORLY DIFFERENTIATED CARCINOMA IN PERIAPPENDICEAL FAT

[page 2 of 3]
[REDACTED]

[REDACTED] By this signature, I attest that the above diagnosis is based upon my personal examination of the slides (and/or other material indicated in the diagnosis).

***Report Electronically Reviewed and Signed Out By [REDACTED] **

Intraoperative Consultation: An intraoperative non-microscopic consultation was obtained and interpreted as: Specimen weighs 110 grams."

FS1A: Left ovary, excision - "Carcinoma," [REDACTED]

FS1B: Endometrial polyp - "Benign endometrial polyp," [REDACTED]

Microscopic Description and Comment: Histological sections of both ovaries show a poorly differentiated carcinoma, consistent with serous adenocarcinoma, in which the tumor cells are arranged predominantly in sheets, with occasional slit-like to rounded glandular spaces. The epithelial nature of the neoplasm is substantiated by positive immunostains for pan-cytokeratin and EMA, while immunostains for vimentin and inhibin are negative in the tumor cells. The tumor is present on the serosal surface of the uterus, with focal extension into the underlying myometrium. The endometrial cavity is not involved. Extensive metastatic deposits are present in the omentum. The soft tissue around the appendix is also involved by carcinoma. Areas of tumor in the omentum display psammoma bodies. The endometrium shows cystic atrophy with a single large endometrial polyp (7.5 cm) with no areas of malignancy.

[REDACTED]

History: The patient is a [REDACTED] with ascites, ovarian mass, multiple nodules in abdomen, pleural effusion and abdominal pain. Operative procedure: Laparotomy, total abdominal hysterectomy, bilateral salpingo-oophorectomy, tumor debulking, omentectomy, appendectomy.

Specimen(s) Received:

- A: UTERUS, CERVIX, BOTH TUBES AND OVARIES
- B: OMENTUM, ROUTINE
- C: APPENDIX

Gross Description The specimens are received in three formalin-filled containers, each labeled with the patient's name. The first container is labeled "uterus, cervix, both tubes and ovaries." It consists of a 110 gram previously opened uterus with attached ovaries and tubes. The right ovary measures 3.5 x 2.5 x 1.8 cm and has been previously opened. The external surface and parenchyma is tan-brown to grey, nodular, and friable. The right fallopian tube measures 4.5 cm in length and up to 0.7 cm in diameter. The external surface has multiple cysts ranging from less than 0.1 to 0.4 cm. Sections of the tube show unremarkable luminal surface. The left ovary measures 2.3 x 1.4 x 0.8 cm and external surface is tan-pink, smooth with a lobulated appearance. Sections show a tan-pink, firm parenchyma grossly involved by tumor. No normal ovarian parenchyma is identified. The left fallopian tube measures 3.5 cm in length and up to 0.6 cm in diameter and is grossly unremarkable. Sections show unremarkable luminal surface. The uterus measures 10.3 cm in length, 4.3 cm cornu-to-cornu and 3.4 cm anteroposteriorly. The serosal surface is tan-pink and smooth with 0.1 to 0.2 cm subserosal cystic lesion. The cervix measures 3 cm in length and up to 2.5 cm in width and is grossly unremarkable. The endocervical canal measures 2.5 cm in length and up to 1.3 cm in diameter and is grossly unremarkable. The endometrial cavity measures 4 cm in length and up to 3.8 cm in width and has a single, 7.5 x 3.5 x 1.5 cm tan-pink, firm fleshy polyp adherent to the posterior endometrium and fundus. The rest of the endometrium is unremarkable and is up to 0.1 cm thick. The myometrium contains

[page 3 of 3]
[REDACTED]

a single, 1.4 cm in diameter leiomyoma and posterior surface. The rest of the myometrium is unremarkable and is up to 1.5 cm thick. Labeled A1 to A3 - right ovary; A4 - right fallopian tube; A5 to A7 - entire left ovary; A8 - left fallopian tube; A9 - anterior cervix; A10 - anterior endomyometrium; A11 - posterior cervix and lower uterine segment; A12 - posterior endomyometrium full thickness; A13 - endometrial polyp with section of posterior endometrium; A14 to A24 - entire endometrial polyp (21, 22 and 23 with endometrium at fundus). Also received in the same container are two cassettes, the first is labeled FS1A and contains a 1x0.9x0.1cm tan firm tissue fragment. Labelled A25. The second cassette is labelled FS1B and contains two, 1cm and 1.8x1x0.1cm tan grey, firm tissue fragment.

[REDACTED]

The second container is labeled "omentum," and contains a 28.5 x 13.5 x 2 cm yellow-pink segment of omentum. The external surface has multiple tan-pink to white firm nodules ranging from less than 1 cm to 1.5 cm. Sections show the entire omentum to be tan-white and firm and grossly involved by tumor. No normal fat is identified.

[REDACTED]

The third container is labeled "appendix," and contains an 8 cm long, up to 0.6 cm in diameter appendix with attached up to 1.5 cm of fat. The serosa and muscularis are missing for a length of 3.4 cm, from 1.8 cm proximal to the tip to 2 cm distal to the resection margin. The serosal surface of the rest of the appendix is tan-pink with multiple firm nodules. Sections show unremarkable luminal surface of the appendix with tan-white firm tumor mass in the adjacent fat. Labeled C1 - section of appendix at tip and luminal random section.

[REDACTED]

[REDACTED]

Synopsis SYNOPTIC REPORTING FORM FOR MALIGNANT OVARIAN NEOPLASMS 1. A neoplasm is PRESENT 2. The HISTOLOGIC DIAGNOSIS is : Serous adenocarcinoma 3. The LOCATION(S) OF THE PRIMARY TUMOR(S) is/are Right and left ovary (synchronous primary tumors) 4. The FIGO GRADE of the tumor is: III (Tumor composed of >50% solid cellular nests) 5. The NUCLEAR (BRODERS') GRADE of the tumor is: G3 (Poorly-differentiated) 6. Tumor IS identified on the ovarian surface(s). 7 Tumor DOES NOT invade the mesovarium. 8. Tumor IS PRESENT around the adjacent fallopian tube. 9. Tumor DOES NOT invade the pelvic soft tissue. 10. Tumor involvement of the pelvic peritoneum is PRESENT. 11. Metastatic involvement of the EXTRAPELVIC PERITONEUM is PRESENT. 12. Metastatic involvement of the omentum is PRESENT. 13. The maximum dimension of tumor implants outside the true pelvis is 28.5 cm. 14. Metastatic involvement of the uterine serosa is PRESENT. 15. Metastatic involvement of the endometrium is ABSENT. 16. Regional lymph node metastases CANNOT BE EVALUATED. 17. The total number of regional lymph nodes examined is 0 18. DETAILED STAGING INFORMATION:

Based on the above information, the PRIMARY TUMOR is classified as:

TNM Scheme	FIGO Scheme	Definition
	T3c	IIIC

Macroscopic peritoneal metastasis beyond true pelvis measuring > 2 cm in greatest dimension
THE REGIONAL LYMPH NODES are classified as: NX (Nodal status cannot be assessed)
THE STATUS OF DISTANT TUMOR SITES is classified as: [REDACTED] (Status cannot be assessed)

The pathologic stage assigned here should be regarded as provisional, and may change after integration of clinical data not provided with this specimen.

Source: NCI Genomic Data Commons file 0861727e-7cfa-474c-bd18-d7ddf70c710e (TCGA-24-1558.62143E5F-4452-47CA-A67C-CD87036424B1.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).